Somatic mutation profile of tumor specimen TCGA-A6-6142-01A (aliquot TCGA-A6-6142-01A-11D-1771-10) from TCGA case TCGA-A6-6142, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 56.1 years (20,485 days).
Specimen TCGA-A6-6142-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ed7168a3-8f1e-4f77-aee4-d57fbf1ffaa3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A6-6142-10A (Blood Derived Normal), aliquot TCGA-A6-6142-10A-01D-1771-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ed25ac4-7b98-448c-8afb-a64f28f8bd0c

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 17, Frame Shift Del 5, Nonsense Mutation 4, Intron 2, Splice Site 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4216C>T p.Q1406* | Nonsense Mutation (SNP) | VAF 14/72 reads (19%) | hotspot (GDC flag); catalogued as rs587782518, CM023011, COSV57321535; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHD4 | c.3164G>A p.R1055H (on ENST00000357008 / NM_001363606.2; = p.R1068H on NM_001273.5) | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs886039915, COSV58894318; ClinVar: pathogenic; called by muse, mutect2
- CRLF2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 20/160 reads (13%) | hotspot (GDC flag); SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1319865856, COSV67493811; called by muse, mutect2, varscan2
- FBXW7 | c.2065C>T p.R689W (on ENST00000281708 / NM_001349798.2; = p.R609W on NM_018315.5) | Missense Mutation (SNP) | VAF 46/116 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55895191, COSV55934968; called by muse, mutect2, varscan2
- TP53 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 17/59 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138729528, CM011013, CM118880, COSV52688031, COSV52713177, COSV52717943, COSV53372849; ClinVar: uncertain significance / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- AKAP9 | c.7331A>G p.N2444S (on ENST00000359028; = p.N2420S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.027); catalogued as COSV62354684; called by muse, mutect2, varscan2
- AMOTL1 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1466689580, COSV100133895; called by mutect2, varscan2
- ATP13A5 | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV60873343; called by muse, mutect2, varscan2
- BNC2 | c.3059C>A p.S1020* | Nonsense Mutation (SNP) | VAF 21/87 reads (24%) | catalogued as COSV101036749; called by muse, mutect2, varscan2
- CDH9 | c.89G>T p.S30I | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV50381618, COSV99141413; called by muse, varscan2
- CENPE | c.3034-1G>A p.X1012_splice | Splice Site (SNP) | VAF 99/253 reads (39%) | catalogued as rs111987461, COSV99478784; called by muse, mutect2, varscan2
- CKMT1B | c.1070G>A p.G357E | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55853249; called by muse, mutect2, varscan2
- CMYA5 | c.6859G>A p.E2287K | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); catalogued as COSV71404201; called by muse, mutect2
- CYP4F3 | c.1042C>A p.P348T | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV55412600; called by muse, mutect2, varscan2
- DDX43 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV64836828; called by muse, mutect2, varscan2
- DIAPH1 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99527098; called by muse, varscan2
- DNAH9 | c.4347C>A p.F1449L | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.572); catalogued as COSV52368703; called by muse, mutect2, varscan2
- DOP1B | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.43); PolyPhen benign (0.009); catalogued as rs551407018, COSV101215725; called by muse, mutect2, varscan2
- DPP4 | c.896A>T p.Y299F | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV62108854; called by muse, mutect2, varscan2
- EDC4 | c.1152T>A p.C384* | Nonsense Mutation (SNP) | VAF 42/123 reads (34%) | catalogued as COSV62767421; called by muse, mutect2, varscan2
- EIF3A | c.3911G>A p.R1304H | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as rs1484391111, COSV64960584; called by muse, mutect2, varscan2
- EPYC | c.434C>G p.T145S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV99664844; called by muse, varscan2
- FAT4 | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 7/58 reads (12%) | catalogued as COSV101271827; called by muse, mutect2, varscan2
- GPRC5C | c.1274A>C p.K425T (on ENST00000652232; = p.K380T on NM_018653.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV61238256; called by muse, mutect2, varscan2
- HLA-DRA | c.205C>T p.R69W | Missense Mutation (SNP) | VAF 21/150 reads (14%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs751526731, COSV66622761; called by muse, mutect2, varscan2
- IGFALS | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1176454073, COSV51907858; called by muse, mutect2, varscan2
- ITIH1 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs142551669; called by muse, mutect2
- KCNC4 | c.917C>T p.T306M | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs200576153, COSV63926384; called by muse, mutect2, varscan2
- KCNJ1 | c.976G>T p.A326S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.147); catalogued as rs775088508, COSV60662520; called by muse, mutect2, varscan2
- KIAA1109 | c.13544G>A p.G4515D | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757850575, COSV52682040, COSV52687041; called by muse, mutect2, varscan2
- KLC1 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs760174989, COSV99871770; called by muse, mutect2, varscan2
- KMT2A | c.7444G>A p.V2482I | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV63290613; called by muse, mutect2, varscan2
- MAP4 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV64243460; called by muse, mutect2, varscan2
- NLRP4 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.534); catalogued as rs768142392, COSV56712077; called by muse, mutect2, varscan2
- NOS1 | c.3955C>T p.R1319W | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773372298, COSV100500172; called by muse, mutect2, varscan2
- OR52D1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 52/222 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.114); catalogued as rs373389868; called by muse, mutect2, varscan2
- OSBP | c.843G>T p.M281I | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as COSV99803286; called by muse, mutect2, varscan2
- OTOA | c.2086G>T p.V696L (on ENST00000286149; = p.V682L on NM_144672.4) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.024); catalogued as COSV53761536; called by muse, mutect2, varscan2
- PBDC1 | c.697A>G p.M233V | Missense Mutation (SNP) | VAF 20/175 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV64896123; called by muse, mutect2, varscan2
- PHF3 | c.1252A>G p.K418E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV50332657; called by muse, mutect2, varscan2
- PKD1 | c.4451C>T p.P1484L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.845); catalogued as rs759853409, COSV99238788; called by muse, mutect2, varscan2
- PRDM5 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs187637689, COSV53358649, COSV53368512; called by muse, mutect2, varscan2
- PRSS35 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs757842601, COSV63800328; called by muse, mutect2, varscan2
- PTPN9 | c.1066G>A p.D356N | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as COSV60725366; called by muse, mutect2, varscan2
- RLN2 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs377215597; called by muse, mutect2, varscan2
- RYR1 | c.9472C>T p.L3158= | Splice Region (SNP) | VAF 10/24 reads (42%) | catalogued as rs770942162, COSV62093985; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR3 | c.1280G>C p.R427P | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs765542021, COSV101213715, COSV66794661; called by muse, mutect2, varscan2
- SCN11A | c.2222C>T p.P741L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs369499148, COSV100181812; called by muse, mutect2, varscan2
- SCN3A | c.1712G>A p.R571H | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs765013479, COSV99327984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPANXN2 | c.92C>A p.P31Q | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100979781, COSV65128866; called by muse, mutect2, varscan2
- ST3GAL4 | c.958C>T p.R320W (on ENST00000392669 / NM_001254758.1; = p.R316W on NM_006278.3) | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs767229905, COSV57106602; called by muse, mutect2, varscan2
- THBD | c.317G>A p.R106H | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs764904057, COSV101001913; called by muse, mutect2, varscan2
- TNXB | c.6071G>A p.R2024H (on ENST00000647633; = p.R1777H on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.921); catalogued as rs767799073, COSV64482909; called by muse, mutect2, varscan2
- VPS13C | c.6481T>C p.F2161L (on ENST00000644861 / NM_020821.3; = p.F2118L on NM_017684.5) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV99829726; called by muse, mutect2
- WWC2 | c.3218T>G p.L1073R | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV67861010, COSV67862338; called by muse, mutect2, varscan2
- XRRA1 | c.1639C>T p.R547C | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.06); PolyPhen benign (0.232); catalogued as rs761489735, COSV58499805; called by muse, varscan2
- ZCCHC4 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs770916713, COSV57182924; called by muse, mutect2, varscan2
- ZNF32 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.129); catalogued as COSV65641873; called by muse, mutect2, varscan2
- ZSCAN20 | c.2896A>G p.K966E | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV63684026; called by muse, mutect2, varscan2
- ADAMTS18 | c.1950del p.R651Gfs*51 | Frame Shift Del (DEL) | VAF 36/132 reads (27%) | called by mutect2, pindel, varscan2
- APC | c.2827del p.S943Qfs*12 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | called by mutect2, pindel, varscan2
- DEF6 | c.1892del p.N631Ifs*5 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- PARPBP | c.1258del p.I420Lfs*3 | Frame Shift Del (DEL) | VAF 47/148 reads (32%) | called by mutect2, pindel, varscan2
- TP53 | c.778_782+7delinsCC p.X260_splice | Splice Site (DEL) | VAF 9/85 reads (11%) | called by pindel, varscan2*
- TRAPPC8 | c.3541_3545del p.I1181Lfs*4 | Frame Shift Del (DEL) | VAF 22/99 reads (22%) | called by mutect2, pindel, varscan2
- TUBGCP5 | c.2783A>C p.K928T | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- ADGRB2 | c.4458C>T p.H1486= (on ENST00000373658 / NM_001364857.2; = p.H1485= on NM_001294335.2) | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs143976016; called by muse, mutect2, varscan2
- ASH2L | c.1461A>T p.G487= | Silent (SNP) | VAF 17/38 reads (45%) | catalogued as COSV51701319; called by muse, mutect2, varscan2
- CLCN4 | c.1011G>T p.L337= | Silent (SNP) | VAF 8/123 reads (7%) | called by muse, mutect2
- DEFB135 | c.24G>A p.L8= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs759597375, COSV66363601; called by muse, mutect2, varscan2
- DOK7 | c.486C>T p.A162= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs371609452, COSV100403504; called by muse, mutect2, varscan2
- EDEM3 | c.1293A>G p.E431= | Silent (SNP) | VAF 63/157 reads (40%) | catalogued as COSV58926952; called by muse, mutect2, varscan2
- EIF5B | c.843A>G p.V281= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV56815232, COSV56815919; called by muse, mutect2, varscan2
- ESCO1 | c.468A>G p.K156= | Silent (SNP) | VAF 76/253 reads (30%) | catalogued as COSV52521892; called by muse, mutect2, varscan2
- GDPD1 | c.720A>G p.E240= | Silent (SNP) | VAF 64/201 reads (32%) | catalogued as COSV52383717; called by muse, mutect2, varscan2
- GJA10 | c.690A>C p.I230= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV65355919; called by muse, mutect2, varscan2
- KATNIP | c.2691C>T p.H897= | Silent (SNP) | VAF 12/87 reads (14%) | catalogued as rs750067826, COSV55174800, COSV55191920; called by muse, mutect2, varscan2
- MLXIP | c.1932C>T p.P644= | Silent (SNP) | VAF 7/68 reads (10%) | catalogued as rs763369656, COSV59834083; called by muse, mutect2, varscan2
- PLD3 | c.1203C>T p.P401= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as rs200131395, COSV99396929; called by muse, mutect2, varscan2
- RPIA | c.201C>T p.S67= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV99376399; called by muse, mutect2, varscan2
- XPNPEP1 | c.1068C>T p.T356= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as rs777918487, COSV59170501; called by mutect2, varscan2
- ZFHX4 | c.9597G>T p.V3199= | Silent (SNP) | VAF 16/115 reads (14%) | catalogued as COSV51485731, COSV99268925; called by muse, mutect2, varscan2
- ZNRF4 | c.699C>T p.H233= | Silent (SNP) | VAF 8/19 reads (42%) | catalogued as rs200409035, COSV99706458; called by muse, mutect2, varscan2
- LINC01098 | n.744T>C | RNA (SNP) | VAF 20/98 reads (20%) | catalogued as rs1263749840; called by muse, mutect2, varscan2
- OBSCN | c.11659+4927G>A | Intron (SNP) | VAF 10/26 reads (38%) | catalogued as rs760283242, COSV52849962; called by muse, mutect2, varscan2
- TCF7L2 | c.1442+671C>T | Intron (SNP) | VAF 18/82 reads (22%) | catalogued as COSV53336375, COSV53339511; called by muse, varscan2
